Gene-level copy-number profile of tumor specimen REBC-ACDL-TTP1-A from REBC case REBC-ACDL, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACDL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5227040a-2608-4828-b5df-45f23c42a906.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACDL-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/0d81611a-d84f-4877-ad88-9dd17564c6a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 123; copy number 2: 58,221; copy number 3: 14.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–686,673, 41 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 123. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
